Somatic mutation profile of tumor specimen C3N-01025-04 (aliquot CPT0083980006) from CPTAC case C3N-01025, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 52.9 years (19,325 days).
Specimen C3N-01025-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec02061c-a7e6-4046-b925-0c27bac5659c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01025-71 (Blood Derived Normal), aliquot CPT0084010002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f96f70ca-e576-4940-a29b-bbfa9a2e7105

The open-access MAF lists 301 somatic variants for this specimen: 198 protein-altering or splice-affecting, 62 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 164, Silent 62, Intron 19, Nonsense Mutation 14, Frame Shift Del 8, RNA 7, 5'UTR 6, Splice Region 4, 5'Flank 4, Splice Site 4, 3'UTR 4, Translation Start Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PKHD1 | c.602+1G>A p.X201_splice | Splice Site (SNP) | VAF 47/288 reads (16%) | catalogued as rs1554223950; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABI2 | c.1112A>G p.Y371C (on ENST00000295851 / NM_001375719.1; = p.Y304C on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs768957658; called by muse, mutect2, varscan2
- ACSM2A | c.812G>A p.C271Y (on ENST00000219054; = p.C192Y on NM_001308169.2) | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV54584010; called by muse, mutect2, varscan2
- ACSM3 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 66/287 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746996527; called by muse, mutect2, varscan2
- ADGRG5 | c.803T>C p.L268P | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1388949326; called by muse, mutect2, varscan2
- ADRA2C | c.1159G>A p.V387I | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1560345598; called by muse, mutect2, varscan2
- ATOH1 | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as rs766059965; called by muse, mutect2, varscan2
- BGLAP | c.188A>G p.Y63C | Missense Mutation (SNP) | VAF 164/320 reads (51%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.75); catalogued as rs1315778145; called by muse, mutect2, varscan2
- BIN1 | c.1309G>T p.A437S | Missense Mutation (SNP) | VAF 37/203 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV52115895; called by muse, mutect2, varscan2
- C10orf71 | c.3052T>A p.W1018R | Missense Mutation (SNP) | VAF 67/157 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1564692884; called by muse, mutect2, varscan2
- CDKN2A | c.377T>G p.V126G | Missense Mutation (SNP) | VAF 266/381 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as CM940231, COSV58684293, COSV58705336; called by mutect2, varscan2
- CFAP70 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 93/180 reads (52%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs1564884169; called by muse, mutect2, varscan2
- CHRNB3 | c.1318A>G p.T440A | Missense Mutation (SNP) | VAF 44/536 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.123); catalogued as rs745393244, COSV104390752; called by muse, mutect2
- CHSY1 | c.1258G>A p.A420T | Missense Mutation (SNP) | VAF 108/837 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as rs756747714, COSV54256644; called by muse, mutect2, varscan2
- COL6A5 | c.6854T>C p.L2285P (on ENST00000312481; = p.L2281P on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/273 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs763254612; called by muse, mutect2, varscan2
- CPA6 | c.1004C>T p.S335F | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52739744; called by muse, mutect2
- CRYBG3 | c.40A>C p.S14R | Missense Mutation (SNP) | VAF 37/180 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1189561209; called by muse, mutect2, varscan2
- DACH2 | c.229A>C p.K77Q | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.232); catalogued as COSV64179661; called by muse, mutect2
- DDC | c.1085T>C p.M362T | Missense Mutation (SNP) | VAF 267/659 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as rs1017626453; called by muse, mutect2, varscan2
- DNER | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 100/239 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV59172217; called by muse, mutect2, varscan2
- DUSP16 | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.141); catalogued as rs775811253; called by muse, mutect2, varscan2
- ELMO2 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 56/173 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.046); catalogued as rs756447733, COSV51682843; called by muse, mutect2, varscan2
- ELOA2 | c.1379C>A p.S460* | Nonsense Mutation (SNP) | VAF 136/681 reads (20%) | catalogued as rs536619955, COSV55293914, COSV99796656; called by muse, mutect2, varscan2
- ERF | c.397C>G p.P133A | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV99724801; called by muse, mutect2, varscan2
- ERICH3 | c.2380G>A p.E794K | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.15); catalogued as COSV100445164; called by muse, mutect2, varscan2
- FAM135B | c.4088G>A p.R1363Q | Missense Mutation (SNP) | VAF 249/706 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52720945; called by muse, mutect2, varscan2
- FN1 | c.3112C>T p.Q1038* | Nonsense Mutation (SNP) | VAF 139/357 reads (39%) | catalogued as COSV60562888; called by muse, mutect2, varscan2
- FTO | c.1274G>T p.G425V | Missense Mutation (SNP) | VAF 104/408 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.129); catalogued as rs376527078; called by muse, varscan2
- GULP1 | c.46A>G p.T16A | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV63068771; called by muse, mutect2, varscan2
- GXYLT1 | c.902T>C p.I301T | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.026); catalogued as rs150955647; called by muse, mutect2, varscan2
- HLA-B | c.893G>T p.W298L | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs41551113, CM077288, COSV69523259; called by muse, varscan2
- IL18RAP | c.1250G>C p.W417S | Missense Mutation (SNP) | VAF 68/217 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV99962503; called by muse, mutect2, varscan2
- ISY1-RAB43 | c.47G>T p.R16L | Missense Mutation (SNP) | VAF 141/562 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.025); catalogued as COSV56440264; called by muse, mutect2, varscan2
- KCNA4 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 82/161 reads (51%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.04); catalogued as rs769344328, COSV60250408; called by muse, mutect2, varscan2
- KEAP1 | c.1105G>C p.V369L | Missense Mutation (SNP) | VAF 100/155 reads (65%) | SIFT tolerated (0.36); PolyPhen benign (0.029); catalogued as COSV50386938, COSV50609562, COSV99061730; called by muse, mutect2, varscan2
- KRT77 | c.1390G>A p.A464T | Missense Mutation (SNP) | VAF 84/184 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs903879117; called by muse, mutect2, varscan2
- LMNB2 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 148/220 reads (67%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as rs375613243; called by muse, mutect2, varscan2
- MAGI2 | c.3706+4C>T | Splice Region (SNP) | VAF 22/98 reads (22%) | catalogued as rs1290658478, COSV62700478; called by muse, mutect2, varscan2
- MMP24 | c.1408T>A p.C470S | Missense Mutation (SNP) | VAF 122/393 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1318179205; called by muse, mutect2, varscan2
- MUC3A | c.8949G>C p.Q2983H | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV60217203; called by muse, mutect2, varscan2
- MYF6 | c.662C>A p.S221Y | Missense Mutation (SNP) | VAF 103/560 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1255848665; called by muse, mutect2, varscan2
- MYH7 | c.5342G>T p.R1781L | Missense Mutation (SNP) | VAF 233/986 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62521871; called by muse, mutect2, varscan2
- NES | c.2790G>C p.E930D | Missense Mutation (SNP) | VAF 113/459 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs377314316; called by muse, mutect2, varscan2
- NLRP12 | c.563del p.G188Dfs*9 | Frame Shift Del (DEL) | VAF 57/151 reads (38%) | catalogued as COSV60743232; called by mutect2, pindel, varscan2
- NOTCH1 | c.2588G>T p.G863V | Missense Mutation (SNP) | VAF 122/336 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53039560; called by muse, mutect2, varscan2
- NPAP1 | c.3043A>G p.M1015V | Missense Mutation (SNP) | VAF 64/169 reads (38%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs772841495; called by muse, mutect2, varscan2
- OPHN1 | c.1801G>T p.V601F | Missense Mutation (SNP) | VAF 125/159 reads (79%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV100830446; called by muse, mutect2, varscan2
- OR2G2 | c.356C>G p.A119G | Missense Mutation (SNP) | VAF 157/327 reads (48%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.698); catalogued as COSV99069624; called by muse, mutect2
- OR2T2 | c.509G>T p.C170F | Missense Mutation (SNP) | VAF 230/763 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1194820225, COSV100737705; called by muse, mutect2, varscan2
- PCDHA12 | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 108/400 reads (27%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.253); catalogued as COSV56487703; called by muse, mutect2, varscan2
- PGM3 | c.436G>T p.V146F | Missense Mutation (SNP) | VAF 66/194 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as rs1270609084; called by muse, mutect2, varscan2
- PLPPR4 | c.1133G>A p.R378Q | Missense Mutation (SNP) | VAF 107/205 reads (52%) | SIFT tolerated (0.33); PolyPhen benign (0.195); catalogued as rs201281186, COSV64564801; called by muse, mutect2, varscan2
- PLXNB2 | c.2485G>C p.G829R | Missense Mutation (SNP) | VAF 55/342 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100834398; called by muse, mutect2, varscan2
- POSTN | c.2501G>A p.R834H | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs200287900, COSV65711996; called by muse, mutect2, varscan2
- PRKD1 | c.1322G>T p.R441L | Missense Mutation (SNP) | VAF 64/172 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV59582684; called by muse, mutect2, varscan2
- PXDNL | c.636T>A p.Y212* | Nonsense Mutation (SNP) | VAF 84/177 reads (47%) | catalogued as rs1354835063; called by muse, mutect2, varscan2
- QRICH2 | c.4136G>A p.R1379H | Missense Mutation (SNP) | VAF 57/153 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772000651, COSV53154869, COSV53158477; called by muse, mutect2, varscan2
- RALGAPA1 | c.1678C>T p.R560C | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV99354771; called by muse, mutect2, varscan2
- RASA3 | c.1422G>T p.R474S | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV61872998; called by muse, mutect2, varscan2
- SEC16B | c.1481C>T p.A494V | Missense Mutation (SNP) | VAF 18/522 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.657); catalogued as rs1407015627; called by muse, mutect2
- SENP3 | c.1342-1G>C p.X448_splice | Splice Site (SNP) | VAF 36/81 reads (44%) | catalogued as rs111727030; called by muse, mutect2, varscan2
- SLC12A3 | c.1459C>T p.Q487* | Nonsense Mutation (SNP) | VAF 110/428 reads (26%) | catalogued as COSV99344921; called by muse, mutect2, varscan2
- SLC28A3 | c.1420A>G p.M474V | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs1004351725; called by muse, mutect2, varscan2
- SLC35D3 | c.143C>A p.T48N | Missense Mutation (SNP) | VAF 80/442 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as COSV100090721; called by muse, mutect2, varscan2
- SOX3 | c.995G>A p.G332D | Missense Mutation (SNP) | VAF 38/56 reads (68%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.601); catalogued as COSV65168434; called by muse, varscan2
- SRPX | c.1090C>G p.Q364E | Missense Mutation (SNP) | VAF 72/101 reads (71%) | SIFT deleterious (0.03); PolyPhen benign (0.315); catalogued as COSV59439146; called by muse, mutect2, varscan2
- SULT6B1 | c.194A>T p.K65M (on ENST00000535679 / NM_001367551.1; = p.K27M on NM_001032377.2) | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1202686068, COSV53195119; called by muse, mutect2, varscan2
- SVIL | c.1499C>T p.P500L | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV63441025; called by muse, mutect2, varscan2
- TLCD5 | c.523G>T p.V175L (on ENST00000375095 / NM_001198671.2; = p.V197L on NM_001198670.2) | Missense Mutation (SNP) | VAF 57/103 reads (55%) | SIFT tolerated (0.44); PolyPhen benign (0.024); catalogued as rs1427627298; called by muse, mutect2, varscan2
- TMEM106C | c.70G>A p.G24S | Missense Mutation (SNP) | VAF 73/422 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV56743129; called by muse, mutect2, varscan2
- TP53 | c.469_471dup p.V157dup | In Frame Ins (INS) | VAF 103/235 reads (44%) | catalogued as COSV53831644; called by mutect2, pindel, varscan2
- TRHDE | c.2321A>G p.Y774C | Missense Mutation (SNP) | VAF 66/136 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53863936; called by muse, mutect2, varscan2
- TRIM33 | c.1172G>A p.R391K | Missense Mutation (SNP) | VAF 74/147 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.049); catalogued as COSV61825547; called by muse, mutect2, varscan2
- TRIM51 | c.1334C>A p.P445H | Missense Mutation (SNP) | VAF 56/192 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55271595; called by muse, mutect2, varscan2
- TRIOBP | c.3065A>G p.D1022G | Missense Mutation (SNP) | VAF 71/364 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs778269633; called by mutect2, varscan2
- TTN | c.61223C>A p.A20408D (on ENST00000591111; = p.A12984D on NM_003319.4) | Missense Mutation (SNP) | VAF 16/62 reads (26%) | PolyPhen probably damaging (0.974); catalogued as COSV60100609; called by muse, mutect2, varscan2
- TTN | c.18328C>A p.P6110T (on ENST00000591111; = p.P5183T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/161 reads (17%) | PolyPhen possibly damaging (0.73); catalogued as COSV100614041; called by muse, mutect2
- UBR5 | c.4207G>T p.G1403C | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.326); catalogued as COSV99641206; called by muse, mutect2, varscan2
- UHRF1BP1L | c.3657G>C p.Q1219H | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.825); catalogued as rs751198927; called by muse, mutect2, varscan2
- ZIM2 | c.605G>T p.R202M | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV55644137; called by muse, mutect2, varscan2
- ABCB5 | c.22G>T p.E8* | Nonsense Mutation (SNP) | VAF 46/174 reads (26%) | called by muse, mutect2, varscan2
- ADAMTS10 | c.611G>C p.G204A | Missense Mutation (SNP) | VAF 143/304 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTSL5 | c.750del p.T251Pfs*69 | Frame Shift Del (DEL) | VAF 18/27 reads (67%) | called by mutect2, pindel, varscan2
- ADGRB1 | c.4534G>A p.E1512K | Missense Mutation (SNP) | VAF 133/460 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- ADPRH | c.559C>A p.P187T | Missense Mutation (SNP) | VAF 29/263 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.6601C>T p.P2201S | Missense Mutation (SNP) | VAF 53/288 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- APC | c.8302A>G p.S2768G | Missense Mutation (SNP) | VAF 60/96 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- APEX1 | c.125C>G p.P42R | Missense Mutation (SNP) | VAF 91/287 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ARPP21 | c.1490C>A p.P497H | Missense Mutation (SNP) | VAF 38/59 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP10A | c.3347C>A p.T1116N | Missense Mutation (SNP) | VAF 34/237 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ATP13A3 | c.40G>T p.E14* | Nonsense Mutation (SNP) | VAF 35/364 reads (10%) | called by muse, mutect2
- ATP6V0A1 | c.1520C>T p.P507L | Missense Mutation (SNP) | VAF 36/342 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BOLA1 | c.383G>A p.G128D | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRD8 | c.1731+1G>C p.X577_splice (on ENST00000254900 / NM_139199.2; = p.X650_splice on NM_006696.4) | Splice Site (SNP) | VAF 67/132 reads (51%) | called by muse, mutect2, varscan2
- BRWD1 | c.1849G>T p.E617* | Nonsense Mutation (SNP) | VAF 98/170 reads (58%) | called by muse, mutect2, varscan2
- C8orf33 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 51/237 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- CASR | c.1939C>A p.Q647K (on ENST00000490131; = p.Q724K on NM_000388.4) | Missense Mutation (SNP) | VAF 52/172 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CDCA7L | c.921G>T p.G307= | Splice Region (SNP) | VAF 16/65 reads (25%) | called by muse, mutect2, varscan2
- CDH22 | c.172G>C p.G58R | Missense Mutation (SNP) | VAF 79/261 reads (30%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- CDKL2 | c.473A>T p.Y158F | Missense Mutation (SNP) | VAF 61/183 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- CDR2 | c.669T>A p.Y223* | Nonsense Mutation (SNP) | VAF 55/214 reads (26%) | called by muse, mutect2, varscan2
- CEP192 | c.5209C>T p.Q1737* | Nonsense Mutation (SNP) | VAF 56/147 reads (38%) | called by muse, mutect2, varscan2
- CEP97 | c.2320C>G p.Q774E | Missense Mutation (SNP) | VAF 32/340 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.012); called by muse, mutect2
- CHD6 | c.5400A>C p.E1800D | Missense Mutation (SNP) | VAF 56/178 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CLSTN2 | c.1688C>A p.P563H | Missense Mutation (SNP) | VAF 48/231 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CNTNAP4 | c.2366-1G>T p.X789_splice | Splice Site (SNP) | VAF 27/94 reads (29%) | called by muse, mutect2, varscan2
- COL6A5 | c.5272G>A p.E1758K (on ENST00000312481; = p.E1754K on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/211 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CSMD3 | c.7063G>A p.G2355S (on ENST00000297405 / NM_001363185.1; = p.G2251S on NM_052900.3) | Missense Mutation (SNP) | VAF 122/620 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD3 | c.4895G>T p.S1632I (on ENST00000297405 / NM_001363185.1; = p.S1528I on NM_052900.3) | Missense Mutation (SNP) | VAF 241/541 reads (45%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.968); called by mutect2, varscan2
- CTAGE9 | c.398A>G p.E133G | Missense Mutation (SNP) | VAF 156/862 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- CYTIP | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- DCDC2C | c.483del p.D162Ifs*16 | Frame Shift Del (DEL) | VAF 21/162 reads (13%) | called by mutect2, pindel, varscan2
- DGKI | c.157A>G p.M53V | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- DIPK1C | c.931C>A p.L311I | Missense Mutation (SNP) | VAF 47/166 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DISP3 | c.484G>T p.G162C | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.445); called by muse, varscan2
- DNAH10 | c.3919C>G p.L1307V (on ENST00000409039; = p.L1246V on NM_207437.3) | Missense Mutation (SNP) | VAF 43/288 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- DNAH6 | c.5757dup p.L1920Tfs*3 | Frame Shift Ins (INS) | VAF 37/226 reads (16%) | called by mutect2, pindel, varscan2
- DNMT3A | c.529G>T p.E177* | Nonsense Mutation (SNP) | VAF 60/160 reads (38%) | called by muse, mutect2, varscan2
- DOCK10 | c.5313C>T p.S1771= | Splice Region (SNP) | VAF 68/188 reads (36%) | called by muse, mutect2, varscan2
- DOCK8 | c.2306T>C p.L769P | Missense Mutation (SNP) | VAF 396/597 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- DPP10 | c.686G>A p.W229* | Nonsense Mutation (SNP) | VAF 19/107 reads (18%) | called by muse, mutect2, varscan2
- ELOA3D | c.1096G>C p.V366L | Missense Mutation (SNP) | VAF 186/1923 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- FAM204A | c.70A>G p.T24A | Missense Mutation (SNP) | VAF 52/110 reads (47%) | SIFT tolerated (0.67); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FER1L5 | c.3913A>T p.I1305F (on ENST00000623019; = p.I1278F on NM_001293083.2) | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- FSTL5 | c.551T>A p.F184Y | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GABRB3 | c.1237G>T p.G413W | Missense Mutation (SNP) | VAF 96/231 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- GALR1 | c.62C>A p.P21Q | Missense Mutation (SNP) | VAF 79/230 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GID8 | c.66G>T p.L22F | Missense Mutation (SNP) | VAF 88/311 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR174 | c.551T>C p.V184A | Missense Mutation (SNP) | VAF 111/191 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR50 | c.973G>C p.D325H | Missense Mutation (SNP) | VAF 68/95 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- GRIN3A | c.2425A>G p.S809G | Missense Mutation (SNP) | VAF 36/275 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- H2AC17 | c.178A>C p.T60P | Missense Mutation (SNP) | VAF 59/298 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- HECTD4 | c.2014C>T p.L672F | Missense Mutation (SNP) | VAF 69/398 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- IGLJ5 | c.23C>A p.P8H | Missense Mutation (SNP) | VAF 19/139 reads (14%) | PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- IGLV3-32 | c.11C>T p.T4I | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- IL1RAPL1 | c.92G>T p.C31F | Missense Mutation (SNP) | VAF 75/119 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNJ12 | c.1213A>G p.S405G | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- KMT2C | c.12314T>G p.L4105R | Missense Mutation (SNP) | VAF 51/247 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LONP1 | c.1484A>C p.E495A | Missense Mutation (SNP) | VAF 135/205 reads (66%) | SIFT deleterious (0.04); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- LOXHD1 | c.573T>G p.D191E | Missense Mutation (SNP) | VAF 43/200 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- MAGEL2 | c.701C>G p.A234G | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT tolerated, low confidence (0.08); called by muse, mutect2, varscan2
- MALT1 | c.1344G>T p.L448F | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MAP3K15 | c.443T>C p.M148T | Missense Mutation (SNP) | VAF 76/122 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MDH1B | c.1534G>T p.E512* | Nonsense Mutation (SNP) | VAF 14/89 reads (16%) | called by muse, mutect2, varscan2
- MGAM2 | c.3826A>G p.I1276V | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MYBPC2 | c.2729A>T p.Y910F | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- MYH8 | c.3608T>C p.M1203T | Missense Mutation (SNP) | VAF 75/375 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- NES | c.845T>A p.L282Q | Missense Mutation (SNP) | VAF 55/247 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NFASC | c.529A>T p.S177C (on ENST00000339876 / NM_001378329.1; = p.S171C on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 164/327 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NLGN1 | c.506G>T p.S169I | Missense Mutation (SNP) | VAF 59/223 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.196); called by muse, varscan2
- NLRP13 | c.1756C>G p.L586V | Missense Mutation (SNP) | VAF 81/207 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NR1D2 | c.705A>C p.Q235H | Missense Mutation (SNP) | VAF 83/162 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- NR2E1 | c.788C>A p.S263Y | Missense Mutation (SNP) | VAF 112/494 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.587); called by muse, varscan2
- NRAP | c.880T>C p.Y294H | Missense Mutation (SNP) | VAF 68/129 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- OR1S2 | c.823C>G p.P275A | Missense Mutation (SNP) | VAF 83/160 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2B2 | c.164T>A p.L55H | Missense Mutation (SNP) | VAF 63/143 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2T11 | c.652A>C p.I218L | Missense Mutation (SNP) | VAF 168/377 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- OR4D11 | c.296C>G p.T99R | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- OR5D16 | c.449T>A p.L150* | Nonsense Mutation (SNP) | VAF 59/173 reads (34%) | called by muse, mutect2, varscan2
- OR5F1 | c.284C>G p.A95G | Missense Mutation (SNP) | VAF 71/260 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PCDHB5 | c.157G>T p.G53C | Missense Mutation (SNP) | VAF 66/141 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PHIP | c.3220_3223delinsCA p.S1074Hfs*4 | Frame Shift Del (DEL) | VAF 43/172 reads (25%) | called by pindel, varscan2*
- PIEZO2 | c.2851A>G p.I951V | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- POF1B | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 49/85 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- PPP6C | c.647T>G p.F216C | Missense Mutation (SNP) | VAF 50/244 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- PRRG3 | c.410del p.G137Vfs*35 | Frame Shift Del (DEL) | VAF 34/60 reads (57%) | called by mutect2, pindel, varscan2
- PTX3 | c.622A>G p.S208G | Missense Mutation (SNP) | VAF 65/514 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- RAPGEFL1 | c.1027G>T p.G343C | Missense Mutation (SNP) | VAF 115/401 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- RASGRF1 | c.606C>A p.D202E | Missense Mutation (SNP) | VAF 47/182 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- RFX6 | c.2380C>A p.P794T | Missense Mutation (SNP) | VAF 61/329 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- RNF175 | c.154C>G p.H52D | Missense Mutation (SNP) | VAF 61/109 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- RYR2 | c.1568G>T p.G523V | Missense Mutation (SNP) | VAF 41/217 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- SART3 | c.931G>A p.E311K (on ENST00000228284; = p.E293K on NM_014706.4) | Missense Mutation (SNP) | VAF 91/235 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- SCAF8 | c.1748G>C p.G583A | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SIM1 | c.1040T>A p.I347N | Missense Mutation (SNP) | VAF 44/266 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2
- SLC39A10 | c.198del p.K66Nfs*21 | Frame Shift Del (DEL) | VAF 25/156 reads (16%) | called by mutect2, pindel, varscan2
- SLC6A13 | c.1709del p.P570Qfs*29 | Frame Shift Del (DEL) | VAF 35/93 reads (38%) | called by mutect2, pindel, varscan2
- SLCO2B1 | c.1022A>T p.Q341L | Missense Mutation (SNP) | VAF 67/143 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- SLFN12L | c.1592T>A p.M531K (on ENST00000260908 / NM_001363830.1; = p.M549K on NM_001195790.1) | Missense Mutation (SNP) | VAF 47/372 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- SOX3 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); called by muse, varscan2
- SOX5 | c.1360G>T p.D454Y | Missense Mutation (SNP) | VAF 56/202 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- SULF1 | c.1087G>T p.D363Y | Missense Mutation (SNP) | VAF 68/142 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM38B | c.693G>T p.M231I | Missense Mutation (SNP) | VAF 108/263 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TNFSF10 | c.588A>G p.I196M | Missense Mutation (SNP) | VAF 54/454 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- TNN | c.1409T>G p.I470R | Missense Mutation (SNP) | VAF 83/330 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTN | c.41702A>T p.K13901M (on ENST00000591111; = p.K6477M on NM_003319.4) | Missense Mutation (SNP) | VAF 99/241 reads (41%) | PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- TTN | c.18329C>T p.P6110L (on ENST00000591111; = p.P5183L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/162 reads (17%) | PolyPhen probably damaging (0.923); called by muse, mutect2
- TTYH1 | c.451G>T p.V151L | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT tolerated (0.81); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- UBN2 | c.2696C>T p.S899F | Missense Mutation (SNP) | VAF 92/224 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- UBR1 | c.2548C>G p.Q850E | Missense Mutation (SNP) | VAF 37/232 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- UNC80 | c.4645C>G p.L1549V | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- VSIG10L | c.1306G>T p.A436S | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- WDR87 | c.2516del p.K839Rfs*10 | Frame Shift Del (DEL) | VAF 60/319 reads (19%) | called by mutect2, pindel, varscan2
- WDSUB1 | c.613C>G p.L205V | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.771); called by muse, mutect2
- ZBTB41 | c.1773A>G p.R591= | Splice Region (SNP) | VAF 72/246 reads (29%) | called by muse, varscan2
- ZFYVE16 | c.508T>C p.S170P | Missense Mutation (SNP) | VAF 53/113 reads (47%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZRANB3 | c.1183C>G p.L395V | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZSCAN25 | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 150/379 reads (40%) | called by muse, mutect2, varscan2
- ADCY10 | c.2115C>A p.I705= | Silent (SNP) | VAF 55/252 reads (22%) | catalogued as COSV63245047; called by muse, mutect2, varscan2
- ARHGAP33 | c.915G>T p.R305= | Silent (SNP) | VAF 77/332 reads (23%) | called by muse, mutect2, varscan2
- ARHGEF28 | c.3138T>C p.N1046= | Silent (SNP) | VAF 95/179 reads (53%) | called by muse, mutect2, varscan2
- ARMC2 | c.1710C>T p.F570= | Silent (SNP) | VAF 130/349 reads (37%) | called by muse, mutect2, varscan2
- ATP10A | c.3348C>T p.T1116= | Silent (SNP) | VAF 34/240 reads (14%) | catalogued as COSV63526874; called by muse, mutect2, varscan2
- ATP6V1B1 | c.408G>T p.G136= | Silent (SNP) | VAF 573/1081 reads (53%) | called by muse, mutect2, varscan2
- C2orf16 | c.4170T>C p.Y1390= | Silent (SNP) | VAF 74/303 reads (24%) | called by muse, mutect2, varscan2
- C6 | c.1494C>A p.P498= | Silent (SNP) | VAF 193/491 reads (39%) | called by muse, mutect2, varscan2
- CDK18 | c.921G>T p.G307= (on ENST00000506784 / NM_212503.3; = p.G277= on NM_002596.4) | Silent (SNP) | VAF 143/285 reads (50%) | called by muse, mutect2, varscan2
- CDSN | c.1140T>C p.C380= | Silent (SNP) | VAF 71/172 reads (41%) | called by muse, mutect2, varscan2
- COL6A6 | c.2550T>C p.A850= | Silent (SNP) | VAF 30/482 reads (6%) | called by muse, mutect2
- DNAH6 | c.6045A>G p.T2015= | Silent (SNP) | VAF 88/150 reads (59%) | catalogued as rs371429757; called by muse, mutect2, varscan2
- FAM135B | c.2484C>A p.P828= | Silent (SNP) | VAF 84/259 reads (32%) | catalogued as COSV99425274; called by muse, mutect2, varscan2
- FAM168A | c.216G>A p.S72= (on ENST00000064778 / NM_001286050.2; = p.S63= on NM_015159.3) | Silent (SNP) | VAF 91/165 reads (55%) | catalogued as rs367764167; called by muse, mutect2, varscan2
- FAM71F1 | c.126G>A p.V42= | Silent (SNP) | VAF 170/416 reads (41%) | called by muse, mutect2, varscan2
- FAM83B | c.3012A>G p.G1004= | Silent (SNP) | VAF 14/101 reads (14%) | called by muse, varscan2
- GASK1B | c.1197A>C p.G399= | Silent (SNP) | VAF 34/250 reads (14%) | called by muse, mutect2, varscan2
- GOLGA8F | c.318G>T p.L106= (on ENST00000526619; = p.L312= on NM_001350920.2) | Silent (SNP) | VAF 37/634 reads (6%) | called by muse, mutect2
- GPR176 | c.309C>G p.T103= | Silent (SNP) | VAF 65/282 reads (23%) | called by muse, mutect2, varscan2
- KAT2A | c.1078C>T p.L360= | Silent (SNP) | VAF 68/225 reads (30%) | catalogued as COSV56790996; called by muse, mutect2, varscan2
- KCNA6 | c.1188C>T p.F396= | Silent (SNP) | VAF 136/371 reads (37%) | catalogued as rs754380838, COSV54974452; called by muse, mutect2, varscan2
- KCNK7 | c.414C>T p.A138= | Silent (SNP) | VAF 20/93 reads (22%) | catalogued as rs766227266; called by muse, mutect2, varscan2
- KCNU1 | c.1348C>T p.L450= | Silent (SNP) | VAF 28/212 reads (13%) | called by muse, mutect2, varscan2
- KIAA2026 | c.6051A>G p.T2017= | Silent (SNP) | VAF 24/223 reads (11%) | catalogued as rs1181233429, COSV101199067; called by muse, mutect2, varscan2
- KLC3 | c.367C>T p.L123= | Silent (SNP) | VAF 34/221 reads (15%) | catalogued as rs1292056692; called by muse, mutect2, varscan2
- LIPH | c.333A>G p.G111= | Silent (SNP) | VAF 30/376 reads (8%) | called by muse, mutect2
- LPAR5 | c.1032G>T p.P344= | Silent (SNP) | VAF 74/156 reads (47%) | called by muse, mutect2, varscan2
- LRRTM1 | c.336G>T p.L112= | Silent (SNP) | VAF 107/493 reads (22%) | catalogued as COSV54443272; called by muse, mutect2, varscan2
- MB21D2 | c.591A>T p.S197= | Silent (SNP) | VAF 149/725 reads (21%) | called by muse, mutect2, varscan2
- MUCL3 | c.927A>G p.E309= | Silent (SNP) | VAF 141/414 reads (34%) | called by muse, mutect2, varscan2
- MYO7B | c.1155C>A p.S385= | Silent (SNP) | VAF 71/242 reads (29%) | called by muse, mutect2, varscan2
- NAALADL2 | c.30C>T p.N10= | Silent (SNP) | VAF 26/300 reads (9%) | catalogued as rs1222307266; called by muse, mutect2
- NEGR1 | c.711C>A p.P237= | Silent (SNP) | VAF 71/172 reads (41%) | called by muse, mutect2, varscan2
- NOS3 | c.2676C>A p.A892= | Silent (SNP) | VAF 44/107 reads (41%) | catalogued as COSV52490523; called by muse, mutect2, varscan2
- NOTCH3 | c.3675C>T p.D1225= | Silent (SNP) | VAF 110/932 reads (12%) | catalogued as rs1406837854; called by muse, mutect2, varscan2
- NUP98 | c.255A>G p.T85= | Silent (SNP) | VAF 38/213 reads (18%) | called by muse, mutect2, varscan2
- OR1D5 | c.726C>T p.A242= | Silent (SNP) | VAF 89/152 reads (59%) | catalogued as rs1173961153; called by muse, mutect2, varscan2
- OR2L2 | c.591A>G p.T197= | Silent (SNP) | VAF 164/334 reads (49%) | catalogued as rs1267865432; called by muse, mutect2, varscan2
- PAX4 | c.96G>A p.R32= | Silent (SNP) | VAF 118/723 reads (16%) | catalogued as rs770946559; called by muse, mutect2, varscan2
- PCDHB5 | c.156G>C p.L52= | Silent (SNP) | VAF 67/143 reads (47%) | called by muse, mutect2, varscan2
- PMF1 | c.486G>C p.L162= | Silent (SNP) | VAF 80/371 reads (22%) | called by muse, mutect2, varscan2
- POM121C | c.2538C>G p.A846= (on ENST00000607367; = p.A604= on NM_001099415.3) | Silent (SNP) | VAF 83/509 reads (16%) | catalogued as rs1160854420; called by mutect2, varscan2
- RAI14 | c.195C>T p.H65= | Silent (SNP) | VAF 71/198 reads (36%) | catalogued as rs192426703; called by muse, mutect2, varscan2
- RGS20 | c.339C>A p.A113= | Silent (SNP) | VAF 46/77 reads (60%) | catalogued as COSV99391905; called by muse, mutect2, varscan2
- RIMS2 | c.2079G>A p.E693= (on ENST00000666250 / NM_001348490.2; = p.E501= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 32/122 reads (26%) | called by muse, varscan2
- RYR1 | c.459C>T p.S153= | Silent (SNP) | VAF 206/534 reads (39%) | catalogued as rs894468761, COSV62109528; ClinVar: likely benign; called by muse, mutect2, varscan2
- RYR3 | c.3112C>A p.R1038= | Silent (SNP) | VAF 37/324 reads (11%) | catalogued as COSV66800192, COSV66804814; called by muse, mutect2, varscan2
- SCN1A | c.5070C>A p.S1690= (on ENST00000303395 / NM_001202435.3; = p.S1679= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 130/325 reads (40%) | called by muse, mutect2, varscan2
- SCN8A | c.5316C>G p.A1772= | Silent (SNP) | VAF 76/196 reads (39%) | called by muse, mutect2, varscan2
- SF3B4 | c.318C>T p.N106= | Silent (SNP) | VAF 61/319 reads (19%) | called by muse, mutect2, varscan2
- SH2B2 | c.492G>T p.V164= | Silent (SNP) | VAF 24/62 reads (39%) | called by muse, mutect2, varscan2
- SHANK1 | c.315T>C p.C105= | Silent (SNP) | VAF 94/297 reads (32%) | called by muse, mutect2, varscan2
- SLC4A8 | c.3204T>C p.D1068= | Silent (SNP) | VAF 5/92 reads (5%) | catalogued as rs1313764223, COSV71615117; called by muse, mutect2
- SNX14 | c.2685C>T p.T895= (on ENST00000314673 / NM_001350535.1; = p.T842= on NM_020468.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 75/185 reads (41%) | called by muse, mutect2, varscan2
- STAT4 | c.849T>C p.S283= | Silent (SNP) | VAF 57/277 reads (21%) | called by muse, mutect2, varscan2
- TCTN1 | c.658C>T p.L220= | Silent (SNP) | VAF 135/657 reads (21%) | called by muse, mutect2, varscan2
- TGFB3 | c.564C>A p.G188= | Silent (SNP) | VAF 129/574 reads (22%) | called by muse, mutect2, varscan2
- TMEM132D | c.1419A>G p.R473= | Silent (SNP) | VAF 76/198 reads (38%) | called by muse, mutect2, varscan2
- TPD52L1 | c.390C>T p.Y130= | Silent (SNP) | VAF 33/251 reads (13%) | called by muse, mutect2, varscan2
- TRPV5 | c.1468C>T p.L490= | Silent (SNP) | VAF 58/178 reads (33%) | called by muse, mutect2, varscan2
- UBR5 | c.4317G>C p.L1439= | Silent (SNP) | VAF 58/284 reads (20%) | catalogued as COSV55297871; called by muse, mutect2, varscan2
- UGGT1 | c.3690T>G p.S1230= | Silent (SNP) | VAF 28/72 reads (39%) | called by muse, mutect2, varscan2
- AC107023.1 | n.26-6287G>T | Intron (SNP) | VAF 55/252 reads (22%) | called by muse, mutect2, varscan2
- ALG8 | c.-13C>T | 5'UTR (SNP) | VAF 135/283 reads (48%) | catalogued as rs370697846; called by muse, mutect2, varscan2
- B9D2 | c.*34C>A | 3'UTR (SNP) | VAF 66/324 reads (20%) | called by muse, mutect2, varscan2
- CCSER1 | c.2095-12070G>C | Intron (SNP) | VAF 86/273 reads (32%) | catalogued as rs922529575; called by muse, mutect2, varscan2
- CD8A | c.-77del | 5'UTR (DEL) | VAF 101/520 reads (19%) | catalogued as rs951166741; called by mutect2, pindel, varscan2
- CDC73 | c.-37G>T | 5'UTR (SNP) | VAF 40/176 reads (23%) | called by muse, varscan2
- CDH15 | chr16:89168930 del G | 5'Flank (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- CRB1 | c.3879-35G>T | Intron (SNP) | VAF 206/409 reads (50%) | called by muse, mutect2, varscan2
- DBF4B | c.1189+381G>A | Intron (SNP) | VAF 38/269 reads (14%) | called by muse, mutect2, varscan2
- DPP4 | c.285+114T>A | Intron (SNP) | VAF 76/210 reads (36%) | called by muse, mutect2, varscan2
- DTHD1 | chr4:36282004 A>C | 5'Flank (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2, varscan2
- EFHC1 | c.*2906G>C | 3'UTR (SNP) | VAF 12/303 reads (4%) | called by muse, mutect2
- FAM3B | c.20-67G>A | Intron (SNP) | VAF 101/172 reads (59%) | called by muse, mutect2, varscan2
- FBLN1 | c.79+38C>T | Intron (SNP) | VAF 5/14 reads (36%) | catalogued as rs1272005726; called by muse, mutect2, varscan2
- GATA4 | c.-40G>A | 5'UTR (SNP) | VAF 193/369 reads (52%) | called by muse, mutect2, varscan2
- GRIK4 | c.-209C>T | 5'UTR (SNP) | VAF 41/75 reads (55%) | called by muse, mutect2, varscan2
- GVINP1 | n.5452del | RNA (DEL) | VAF 66/172 reads (38%) | called by mutect2, pindel, varscan2
- HYDIN | c.2075+393A>T | Intron (SNP) | VAF 30/251 reads (12%) | catalogued as COSV55483522; called by muse, mutect2, varscan2
- IDH3B | c.915+26T>G | Intron (SNP) | VAF 88/465 reads (19%) | called by muse, mutect2, varscan2
- IGKV1-16 | c.-21C>A | 5'UTR (SNP) | VAF 73/293 reads (25%) | called by muse, mutect2, varscan2
- LINC02448 | n.261T>C | RNA (SNP) | VAF 34/152 reads (22%) | called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85941C>G | Intron (SNP) | VAF 144/335 reads (43%) | called by muse, mutect2, varscan2
- OR52A4P | n.872A>G | RNA (SNP) | VAF 24/65 reads (37%) | catalogued as rs760266878; called by muse, mutect2, varscan2
- OSGIN1 | n.1380G>C | RNA (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2, varscan2
- PIK3C3 | c.531+47A>C | Intron (SNP) | VAF 70/310 reads (23%) | called by muse, mutect2, varscan2
- PTPRVP | n.4024-32G>C | Intron (SNP) | VAF 25/98 reads (26%) | called by muse, mutect2, varscan2
- RAB11B | chr19:8390329 C>A | 5'Flank (SNP) | VAF 21/28 reads (75%) | called by muse, mutect2, varscan2
- RAB35 | c.*607G>C | 3'UTR (SNP) | VAF 138/385 reads (36%) | called by muse, mutect2, varscan2
- RPS19 | c.*34T>G | 3'UTR (SNP) | VAF 96/247 reads (39%) | called by muse, mutect2, varscan2
- SESN3 | c.937+20_937+27dup | Intron (INS) | VAF 34/90 reads (38%) | called by mutect2, varscan2
- SKOR1 | chr15:67822074 G>C | 5'Flank (SNP) | VAF 34/327 reads (10%) | called by muse, mutect2, varscan2
- SLC66A1L | n.308C>A | RNA (SNP) | VAF 64/303 reads (21%) | called by muse, mutect2, varscan2
- SNORD116-17 | chr15:25088565 C>A | 3'Flank (SNP) | VAF 30/87 reads (34%) | called by muse, mutect2, varscan2
- SPTA1 | c.6121-9T>A | Intron (SNP) | VAF 117/244 reads (48%) | called by muse, mutect2, varscan2
- SSPOP | n.2535A>G | RNA (SNP) | VAF 28/166 reads (17%) | called by muse, varscan2
- SUGT1P4-STRA6LP | n.1258G>C | RNA (SNP) | VAF 43/281 reads (15%) | called by muse, mutect2, varscan2
- SYTL2 | c.1459+489C>T | Intron (SNP) | VAF 9/138 reads (7%) | catalogued as rs1411410257; called by muse, mutect2
- TMPRSS7 | c.429+987T>C | Intron (SNP) | VAF 62/288 reads (22%) | called by muse, mutect2, varscan2
- TREML4 | c.506+2288G>A | Intron (SNP) | VAF 8/43 reads (19%) | called by muse, varscan2
- ZIC4 | c.-16+865A>G | Intron (SNP) | VAF 120/506 reads (24%) | called by muse, varscan2
- ZNF720 | c.361+1566A>G | Intron (SNP) | VAF 19/79 reads (24%) | called by muse, mutect2, varscan2
